Somatic mutation profile of tumor specimen TCGA-19-2629-01A (aliquot TCGA-19-2629-01A-01D-1495-08) from TCGA case TCGA-19-2629, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.9 years (22,257 days).
Specimen TCGA-19-2629-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 291a0b37-7272-41b8-b861-db88fdb9d283.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-2629-10A (Blood Derived Normal), aliquot TCGA-19-2629-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12ebb080-e96e-4145-a1c6-91df8bf6cb45

The open-access MAF lists 93 somatic variants for this specimen: 72 protein-altering or splice-affecting, 17 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 17, Frame Shift Del 13, In Frame Del 7, Nonsense Mutation 3, Splice Site 2, Frame Shift Ins 2, RNA 2, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 45/136 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3R1 | c.1382_1384del p.R461_E462delinsQ (on ENST00000521381 / NM_181523.3; = p.R191_E192delinsQ on NM_181504.4) | In Frame Del (DEL) | VAF 28/82 reads (34%) | hotspot (GDC flag); catalogued as COSV57135274; called by mutect2, pindel, varscan2
- AKAP11 | c.5002A>G p.S1668G | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV50295843; called by muse, mutect2, varscan2
- ARHGAP32 | c.4241C>G p.P1414R (on ENST00000310343 / NM_001378025.1; = p.P1065R on NM_014715.4) | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV59846407; called by muse, mutect2, varscan2
- CERS6 | c.215A>G p.N72S | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs372014490; called by muse, mutect2, varscan2
- CFTR | c.1079C>G p.T360R | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as rs75053309, CM983548, COSV50048586; called by muse, mutect2, varscan2
- CHRNA10 | c.907A>G p.M303V | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as rs762589292, COSV51704108; called by muse, mutect2
- CYP2E1 | c.1162G>C p.V388L | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV53313109, COSV99428836; called by muse, mutect2, varscan2
- CYP4F12 | c.1543C>T p.R515W | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.204); catalogued as rs1045250790, COSV61173169; called by muse, mutect2, varscan2
- CYTH4 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV50632022; called by muse, mutect2, varscan2
- DNAJB4 | c.38A>G p.K13R | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT tolerated (0.91); PolyPhen benign (0.074); catalogued as COSV66131521; called by muse, mutect2, varscan2
- DPYSL5 | c.1438_1440del p.K480del | In Frame Del (DEL) | VAF 18/73 reads (25%) | catalogued as rs772460158; called by mutect2, pindel
- EVA1A | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs761321988, COSV52057958; called by muse, mutect2, varscan2
- FAM234B | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750265649, COSV52194244; called by muse, mutect2, varscan2
- FAT2 | c.3695T>C p.I1232T | Missense Mutation (SNP) | VAF 95/248 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs1485991417, COSV55818194; called by muse, mutect2, varscan2
- FER1L6 | c.2335G>A p.V779M | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.715); catalogued as rs1471830435, COSV67549473; called by muse, mutect2, varscan2
- FXN | c.325G>T p.E109* (on ENST00000377270; = p.E184* on NM_000144.5) | Nonsense Mutation (SNP) | VAF 26/165 reads (16%) | catalogued as COSV66009706; called by muse, mutect2, varscan2
- H3C7 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.049); catalogued as COSV55099706; called by muse, mutect2, varscan2
- JMJD1C | c.5230_5232del p.E1744del | In Frame Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs1378403076; called by pindel, varscan2
- KIAA0319 | c.2570T>C p.I857T | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV65497819; called by muse, mutect2, varscan2
- KIDINS220 | c.4160A>G p.Y1387C | Missense Mutation (SNP) | VAF 108/300 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56752530; called by muse, mutect2, varscan2
- LGI2 | c.543G>T p.W181C | Missense Mutation (SNP) | VAF 130/224 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1158549773, COSV66122823; called by muse, mutect2, varscan2
- MCHR1 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs199697488, COSV50760980; called by muse, mutect2, varscan2
- MFAP3L | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as COSV64372093; called by muse, mutect2, varscan2
- MT1A | c.43T>C p.C15R | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs917775878, COSV51947321; called by muse, mutect2
- MYH4 | c.4993A>T p.I1665F | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV55116753; called by muse, mutect2, varscan2
- MYH7B | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); catalogued as rs1190716212, COSV53418992; called by muse, mutect2, varscan2
- NDUFS2 | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as rs534026057, COSV57154544; called by muse, mutect2, varscan2
- NEB | c.5921A>G p.D1974G | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51131689; called by muse, mutect2, varscan2
- NEPRO | c.1537A>G p.M513V | Missense Mutation (SNP) | VAF 89/226 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs774892630, COSV55606398; called by muse, mutect2, varscan2
- NICN1 | c.206A>C p.H69P | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.808); catalogued as COSV56469404; called by muse, mutect2, varscan2
- OR6K2 | c.257T>C p.L86P | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs1376170463, COSV62743389; called by muse, varscan2
- PCDH18 | c.2787C>A p.D929E | Missense Mutation (SNP) | VAF 41/220 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100787264, COSV61267815; called by muse, mutect2, varscan2
- PKHD1L1 | c.5882A>G p.N1961S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.92); PolyPhen benign (0.006); catalogued as COSV65741649; called by muse, mutect2
- PTPRT | c.2161C>T p.R721C | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs776134993, COSV61967335, COSV62035210; called by muse, mutect2, varscan2
- RAB23 | c.664_667del p.Q222Gfs*24 | Frame Shift Del (DEL) | VAF 33/177 reads (19%) | catalogued as rs764844543; called by pindel, varscan2
- RNASE4 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs756611890, COSV59011978, COSV59012680; called by muse, mutect2, varscan2
- SEPTIN10 | c.59C>G p.T20R | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.052); catalogued as COSV61780023; called by muse, mutect2
- SETBP1 | c.3785G>C p.R1262T | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.116); catalogued as COSV56315003, COSV56319673; called by muse, mutect2
- SPACA1 | c.520A>C p.K174Q | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs1223017322, COSV52759622; called by muse, mutect2, varscan2
- SPOCK3 | c.279G>A p.M93I | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV62723736; called by muse, mutect2, varscan2
- SSR2 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 40/95 reads (42%) | catalogued as COSV55303699; called by muse, mutect2, varscan2
- SYT13 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs753970325, COSV50073275; called by muse, mutect2, varscan2
- TDRD7 | c.1985G>T p.C662F | Missense Mutation (SNP) | VAF 107/303 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.082); catalogued as COSV62429163, COSV62429170; called by muse, mutect2, varscan2
- TENM4 | c.3250A>G p.I1084V | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.891); catalogued as rs1286642519, COSV53623161; called by muse, mutect2, varscan2
- TIMD4 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780115131, COSV50854208; called by muse, mutect2
- TMED5 | c.661_664del p.F221Kfs*13 | Frame Shift Del (DEL) | VAF 45/124 reads (36%) | catalogued as rs1473965497; called by mutect2, pindel, varscan2
- TMEM115 | c.305_307del p.F102del | In Frame Del (DEL) | VAF 18/169 reads (11%) | catalogued as rs762270049; called by pindel, varscan2
- TMEM214 | c.368T>A p.L123Q | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53192276; called by muse, mutect2, varscan2
- TTC22 | c.124C>A p.R42S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV100988156; called by muse, mutect2, varscan2
- TULP1 | c.598A>G p.K200E | Missense Mutation (SNP) | VAF 43/325 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.76); catalogued as COSV57692451; called by muse, mutect2, varscan2
- UGT2A3 | c.996+2T>C p.X332_splice | Splice Site (SNP) | VAF 23/317 reads (7%) | catalogued as COSV52359732; called by muse, mutect2
- USP29 | c.1189A>G p.T397A | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.285); catalogued as rs1568456221, COSV54141953; called by muse, mutect2, varscan2
- VEPH1 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62878221; called by muse, mutect2, varscan2
- ZNF407 | c.344C>A p.T115N | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV55250088; called by muse, mutect2
- ARID2 | c.4017_4018del p.N1340Lfs*12 | Frame Shift Del (DEL) | VAF 28/80 reads (35%) | called by mutect2, pindel, varscan2
- ATRX | c.1073_1074del p.K358Tfs*3 | Frame Shift Del (DEL) | VAF 76/121 reads (63%) | called by pindel, varscan2
- CNOT1 | c.6447_6451del p.N2149Kfs*7 | Frame Shift Del (DEL) | VAF 77/213 reads (36%) | called by mutect2, pindel, varscan2
- DDX17 | c.1282_1283del p.K428Efs*4 | Frame Shift Del (DEL) | VAF 24/199 reads (12%) | called by mutect2, pindel, varscan2
- DGAT1 | c.1230del p.S411Rfs*9 | Frame Shift Del (DEL) | VAF 18/81 reads (22%) | called by mutect2, pindel*, varscan2
- DNAH9 | c.9933+5_9933+8del p.X3311_splice | Splice Site (DEL) | VAF 10/58 reads (17%) | called by pindel, varscan2
- GMPR2 | c.829_831del p.K277del (on ENST00000355299 / NM_001351022.2; = p.K295del on NM_016576.5) | In Frame Del (DEL) | VAF 14/57 reads (25%) | called by pindel, varscan2
- HOMER1 | c.66_68del p.K22del | In Frame Del (DEL) | VAF 106/278 reads (38%) | called by pindel, varscan2
- HSDL2 | c.555del p.E185Dfs*65 | Frame Shift Del (DEL) | VAF 32/131 reads (24%) | called by mutect2, pindel, varscan2
- MYO5B | c.1708_1709del p.D570Hfs*4 | Frame Shift Del (DEL) | VAF 41/140 reads (29%) | called by pindel, varscan2
- PSMC3 | c.375_376del p.K125Nfs*18 | Frame Shift Del (DEL) | VAF 59/177 reads (33%) | called by mutect2, pindel, varscan2
- SCAPER | c.1342_1344del p.E448del | In Frame Del (DEL) | VAF 7/26 reads (27%) | called by pindel, varscan2
- SPEF2 | c.3900dup p.V1301Sfs*18 | Frame Shift Ins (INS) | VAF 9/104 reads (9%) | called by mutect2, pindel
- TMIGD2 | c.347_348del p.V116Gfs*4 | Frame Shift Del (DEL) | VAF 81/359 reads (23%) | called by mutect2, pindel, varscan2
- TMPRSS6 | c.410del p.G137Dfs*19 | Frame Shift Del (DEL) | VAF 27/68 reads (40%) | called by mutect2, pindel, varscan2
- USP53 | c.2543_2544del p.S848Cfs*9 | Frame Shift Del (DEL) | VAF 22/120 reads (18%) | called by pindel, varscan2
- VWF | c.7525dup p.D2509Gfs*24 | Frame Shift Ins (INS) | VAF 23/176 reads (13%) | called by mutect2, pindel, varscan2
- CFAP100 | c.801G>A p.S267= | Silent (SNP) | VAF 25/183 reads (14%) | catalogued as rs757315451, COSV61502891; called by muse, mutect2, varscan2
- FAM83G | c.397C>T p.L133= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs763540091, COSV58757414; called by muse, mutect2, varscan2
- FREM2 | c.6786A>G p.E2262= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as COSV54835207; called by muse, mutect2, varscan2
- H4-16 | c.258T>C p.D86= | Silent (SNP) | VAF 18/144 reads (13%) | catalogued as rs759672780, COSV63762044; called by muse, mutect2, varscan2
- ITPRID1 | c.825G>A p.E275= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV60073208; called by muse, mutect2, varscan2
- KCTD9 | c.1149C>T p.H383= | Silent (SNP) | VAF 42/265 reads (16%) | catalogued as COSV55339914; called by muse, mutect2, varscan2
- KRTAP10-2 | c.159G>C p.V53= | Silent (SNP) | VAF 40/96 reads (42%) | catalogued as rs587703858, COSV59959248; called by muse, mutect2, varscan2
- MYH1 | c.5685C>A p.V1895= | Silent (SNP) | VAF 66/183 reads (36%) | catalogued as COSV56846965, COSV56856675; called by muse, mutect2, varscan2
- NCALD | c.447A>G p.T149= | Silent (SNP) | VAF 45/135 reads (33%) | catalogued as COSV55272126; called by muse, mutect2, varscan2
- NCOA2 | c.1323T>C p.F441= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as COSV71763846; called by muse, mutect2, varscan2
- NUP210 | c.501G>A p.A167= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs1344211903, COSV54405410; called by muse, mutect2, varscan2
- ODF2L | c.1422G>A p.A474= (on ENST00000317336; = p.A445= on NM_020729.3) | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as rs372029682; called by muse, mutect2, varscan2
- OSBP2 | c.699G>A p.A233= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as rs1249967056, COSV60241873; called by muse, mutect2, varscan2
- POLR3D | c.513C>T p.N171= | Silent (SNP) | VAF 37/223 reads (17%) | catalogued as rs1207239892, COSV60570992; called by muse, mutect2, varscan2
- SGSH | c.927C>T p.S309= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as rs1385473515, COSV58339086; called by muse, mutect2, varscan2
- TLR3 | c.933G>A p.Q311= | Silent (SNP) | VAF 13/142 reads (9%) | catalogued as COSV57168218; called by muse, mutect2
- ZNF142 | c.48G>A p.E16= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as COSV63719709; called by muse, mutect2, varscan2
- ANKRD20A4P | c.*1A>G | 3'UTR (SNP) | VAF 11/48 reads (23%) | catalogued as rs750366282, COSV100628549; called by muse, mutect2, varscan2
- DNAH8 | chr6:38722913 G>A | 5'Flank (SNP) | VAF 6/42 reads (14%) | catalogued as COSV59481432; called by mutect2, varscan2
- IGHV1-12 | n.135A>G | RNA (SNP) | VAF 21/91 reads (23%) | catalogued as rs370639070; called by muse, mutect2, varscan2
- SSPOP | n.1643C>A | RNA (SNP) | VAF 6/45 reads (13%) | catalogued as COSV50487201; called by muse, mutect2, varscan2
